Somatic mutation profile of tumor specimen TCGA-13-0764-01A (aliquot TCGA-13-0764-01A-03W-0371-08) from TCGA case TCGA-13-0764, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 62.9 years (22,965 days).
Specimen TCGA-13-0764-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a7a76ef-464c-4a2a-9b79-b0d616be8441.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0764-10A (Blood Derived Normal), aliquot TCGA-13-0764-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25538d2e-9eff-4891-bb31-5eda11ca6370

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Ins 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 221/264 reads (84%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AURKC | c.248G>T p.G83V (on ENST00000302804 / NM_001015878.2; = p.G49V on NM_003160.3) | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); catalogued as COSV100248748; called by muse, varscan2
- BMPR1B | c.928A>C p.S310R | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV99215441; called by muse, mutect2, varscan2
- CD163 | c.35_36del p.S12Wfs*4 | Frame Shift Del (DEL) | VAF 28/244 reads (11%) | catalogued as rs761945186; called by pindel, varscan2
- DGKB | c.1970A>T p.E657V | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99336886; called by muse, mutect2, varscan2
- FOXL2 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.615); catalogued as COSV100374369, COSV57728033; called by muse, mutect2
- GRB10 | c.33G>C p.L11F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100239827; called by muse, varscan2
- ILKAP | c.523T>G p.F175V | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as COSV99610892, COSV99611274; called by muse, varscan2
- MGAM | c.4489G>A p.V1497M | Missense Mutation (SNP) | VAF 53/65 reads (82%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs201533344; called by muse, mutect2, varscan2
- MYC | c.1140G>C p.Q380H (on ENST00000377970; = p.Q395H on NM_002467.6) | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.091); catalogued as COSV52368869, COSV52375011, COSV99420160; called by muse, mutect2, varscan2
- NOL4 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as rs202220763, COSV99305273; called by muse, mutect2, varscan2
- PPP3CA | c.478T>A p.F160I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100547375; called by muse, mutect2
- SGK2 | c.847G>C p.V283L | Missense Mutation (SNP) | VAF 81/568 reads (14%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.935); catalogued as COSV100414567; called by muse, varscan2
- TNIK | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 76/424 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99455415; called by muse, mutect2, varscan2
- ZNF608 | c.699dup p.H234Afs*34 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | catalogued as rs780943893; called by mutect2, pindel
- INPP5D | c.1791+2_1791+24del p.X597_splice (on ENST00000445964 / NM_001017915.3; = p.X596_splice on NM_005541.5) | Splice Site (DEL) | VAF 42/94 reads (45%) | called by mutect2, pindel
- PRR16 | c.830dup p.I278Yfs*47 (on ENST00000407149 / NM_001300783.2; = p.I255Yfs*47 on NM_016644.2) | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- ETV6 | c.321T>A p.P107= | Silent (SNP) | VAF 32/316 reads (10%) | catalogued as COSV101122407; called by muse, varscan2
- MTHFD1 | c.738A>G p.K246= | Silent (SNP) | VAF 52/93 reads (56%) | catalogued as COSV99386599; called by muse, varscan2
- TGFBI | c.528G>A p.V176= | Silent (SNP) | VAF 63/184 reads (34%) | catalogued as COSV100526286; called by muse, varscan2
